Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98D, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98D-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

Pathology Report:

ICD-O-3
Mesothelioma, biphasic
malignant 96531.3
Site @ Pleura, mesothelial
C38.4
4/3/12/14

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Parietal visceral pleura; pleurectomy:

- Biphasic mesothelioma, see parameters.

B. Parietal visceral pleura; pleurectomy:

- Biphasic mesothelioma, see parameters and comment.

C. Lymph node #7; biopsy:

- Two of four lymph nodes with metastatic mesothelioma, epithelioid (2/4).

D. Lymph node 4R; biopsy:

- Five of five lymph nodes, no tumor (0/5).

E. Lymph node #8; biopsy:

- One lymph node with metastatic mesothelioma, epithelioid (1/1).

F. Lymph node #11; biopsy:

- Two lymph nodes, no tumor (0/2).

Thoracic Mesothelioma Pathologic Parameters

Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural resection

Tumor Site: Right pleura

Tumor Configuration and Size: Diffuse, maximum thickness: 4.6 cm

MICROSCOPIC

Histologic Type: Biphasic mesothelioma (40% epithelioid, 60% sarcomatoid)

Tumor Extension:

Into but not through diaphragm

Lung parenchyma

Venous/Lymphatic (Large/Small Vessel) Invasion: Absent

Margins: Cannot be assessed

Additional Pathologic Findings: Pleural plaques with focal calcifications

Pathologic Staging (pTNM)

*Primary Tumor (pT)

[page 2 of 4]
pT2: Tumor involves any of the ipsilateral pleural surfaces with at least 1 of the following: invasion of diaphragmatic muscle, invasion of lung parenchyma

Regional Lymph Nodes (pN)

pN2: Metastases in the subcarinal lymph node(s) and/or the ipsilateral internal mammary or mediastinal lymph node(s)

Number examined: 12

Number involved: 3

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

Immunohistochemistry with appropriate controls demonstrates that the epithelioid component is positive for calretinin and nuclear WT-1 and negative for MOC31 consistent with mesothelioma. The sarcomatoid component has weaker staining with both mesothelial markers.

xxxx

☐ M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ M.D., Ph.D.

Electronically Signed Out by ☐, M.D.

Clinical History:

The patient is an -year-old male with mesothelioma of the lung undergoing a right thoracotomy, pleurectomy and bronchoscopy.

Specimens Received:

A: Mesothelioma parietal visceral pleura

B: Mesothelioma parietal visceral pleura

C: #7

D: 4R

E: #8

F: #11

Gross Description:

The specimens are received in six containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Mesothelioma parietal visceral pleura". Received fresh and placed in formalin is an oriented 806.7 g, 25 x 15 x 6 cm in overall dimension pleurectomy specimen. The specimen has a volumetric displacement of approximately 650-700 mL. A stitch designates the

[page 3 of 4]
diaphragmatic surface. The ragged red-brown diaphragmatic surface measures 21 x 14.5 cm, is up to 0.8 cm maximum thickness and is inked black. There is a 13.5 x 7.5 cm portion of smooth, pink-white abdominal peritoneum which measures up to 0.1 cm in thickness and is inked blue. Serial sectioning reveals diffusely, nodular, firm tan-pink parietal pleura and visceral pleura containing shaggy, soft gray-brown remnants of lung parenchyma with scattered anthracotic pigment. Serial sectioning reveals firm, solid whorled white confluent nodules scattered throughout with a thickness up to 0.9 cm. The largest area of thickening is located along the peripheral edge of the diaphragmatic surface, measures up to 4.6 cm maximum thickness, abuts black ink and bulges into the surrounding soft lobules of adipose tissue. This portion has an intervening septum of soft, glistening yellow adipose tissue. Additional thickened areas subjacent to the diaphragmatic surface focally come to within 0.2 cm of blue ink (abdominal peritoneum). No pericardium is grossly identified.

Gross photographs are taken. Representative sections are taken as follows:

- A1-A2: Nodule to black ink (diaphragmatic surface)
- A3: Nodule to blue ink (diaphragmatic peritoneum)
- A4: Bulging nodule into the surrounding adipose
- A5-A7: Fused visceral and parietal pleura with remnants of lung parenchyma
- A8: Thickest area of remaining red-brown muscle fibers of the diaphragm and nodule

B. The second container is additionally identified as, "2. mesothelioma parietal visceral pleura ". Received fresh and placed in formalin is a 218.7 g, 20 x 15 x 3 cm in overall dimension unoriented, slightly conical-shaped pleurectomy specimen. The specimen has a volumetric displacement of approximately 250 mL. The specimen is diffusely thickened and fused. The outer surface is shaggy, mottled tan-pink to gray with yellow streaks and with visible ridged imprints of the ribs. The inner lining of the visceral pleura contains soft, shaggy remnants of brown lung parenchyma with scattered anthracotic pigment. Serial sectioning reveals confluent nodular white-gray cut surfaces measuring up to 1.4 cm maximum thickness. There are also scattered areas of calcification. Gross photographs are taken. Representative sections are submitted as B1-B6 (B6 after slight decalcification).

C. The third container is additionally identified as, "#7". Received fresh and placed in formalin is a 2.7 x 2.1 x 1.1 cm aggregate of rubbery, tan-yellow to gray-black tissue fragments (4 total). 4 rubbery, partially fragmented lymph node candidates are identified ranging in size from 0.8-1.9 cm greatest dimension. The specimen is submitted entirely as follows:

- C1: 3 lymph nodes
- C2: One lymph node, bisected

[page 4 of 4]
D. The fourth container is additionally identified as, "4R". Received fresh and placed in formalin is a 2.2 x 2.1 x 0.9 cm aggregate of rubbery, tan-yellow to gray-black tissue fragments (5 total). Each fragment contains gray-black fragmented lymph node candidates ranging in size from 0.6-1.3 cm in greatest dimension. The specimen is submitted entirely as follows:

D1: 2 lymph nodes

D2: 3 lymph nodes

E. The fifth container is additionally identified as, "#8". Received fresh and placed in formalin is a 1.1 x 0.9 x 0.4 cm ovoid, rubbery gray-black lymph node candidate. The specimen is bisected and submitted entirely as E1.

F. The sixth container is additionally identified as, "#11". Received fresh and placed in formalin are 2 fragments of rubbery, gray-black to tan-yellow lymph node candidates ranging in size from 0.5-0.6 cm greatest dimension. The specimen is submitted in toto as F1.

xxx

□

Source: NCI Genomic Data Commons file 15069d7d-96f7-4c47-8f12-def84a9ce5ff (TCGA-3U-A98D.8F55DF05-CE3D-42FF-9247-480F3CADD030.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).